Surgical pathology report (de-identified scan), TCGA case TCGA-DD-A73D, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-A73D-01A (Primary Tumor).

Female

ICD-O-3
Carcinoma, hepatocellular ^{NOS}
Site Liver C22.0 8/70/13
QW 8/14/13

DIAGNOSIS:

A. Liver, segment VII, wedge resection: Well-differentiated hepatocellular carcinoma (grade 1 of 4), forming a single mass, 4.8 x 4.0 x 3.5 cm. The tumor is confined to the liver. The liver parenchyma resection margin is negative for tumor (tumor free margin, 1.0 cm). Macroscopic large vessel (venous) invasion is absent. Microscopic (small vessel) invasion is present. No regional lymph nodes identified. The non-neoplastic hepatic parenchyma shows chronic hepatitis C changes with minimal (grade 1 of 4) activity and cirrhosis (stage 4 of 4).

Pathologic Staging: AJCC pT2 pNX pMX (7th edition, 2012)

B. Gallbladder, cholecystectomy: Chronic cholecystitis and cholelithiasis.

Interpreted by:
Report electronically signed by
Transcribed by:

ADDENDUM:

A reticulin stain performed on the tumor mass shows absence of reticular framework. The tumor cells are positive for glypican-3, supporting the diagnosis. Reticulin and trichrome stains on the nonneoplastic parenchyma support the presence of cirrhosis.

I:IPAA Discrepancy		☒

Source: NCI Genomic Data Commons file 62438ab6-7cb3-4e73-9df2-11747e8003be (TCGA-DD-A73D.6C9BA4B3-78FD-4D16-A420-5C98BCEFD55D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).